Somatic mutation profile of tumor specimen TCGA-OR-A5K0-01A (aliquot TCGA-OR-A5K0-01A-11D-A29I-10) from TCGA case TCGA-OR-A5K0, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 69.5 years (25,400 days).
Specimen TCGA-OR-A5K0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4949f99-36a6-4cf4-b7a7-39f5fd53ca42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5K0-10B (Blood Derived Normal), aliquot TCGA-OR-A5K0-10B-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adad3640-7b9d-4a2a-9d97-a157200a450d

The open-access MAF lists 63 somatic variants for this specimen: 44 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 32, Silent 19, Frame Shift Del 6, In Frame Del 4, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 220/232 reads (95%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV64731793, COSV64731830, COSV64732212; called by muse, mutect2, varscan2
- HUWE1 | c.9581T>C p.F3194S | Missense Mutation (SNP) | VAF 104/199 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs782393002; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMDHD2 | c.317_319del p.F106del | In Frame Del (DEL) | VAF 72/158 reads (46%) | catalogued as rs1472174670; called by mutect2, varscan2
- CACNA1G | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs778920307; called by muse, varscan2
- CCR4 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1432823572, COSV58381780; called by muse, mutect2, varscan2
- CMYA5 | c.6205G>T p.V2069F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs547347301; called by muse, varscan2
- ELL3 | c.22_23del p.L8Efs*15 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs747002076; called by pindel, varscan2
- ILDR1 | c.1160C>G p.S387C (on ENST00000344209 / NM_001199799.2; = p.S343C on NM_175924.4) | Missense Mutation (SNP) | VAF 71/73 reads (97%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs746732835, COSV56547533; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEB2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/454 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1377385127; called by muse, mutect2
- MAGED1 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV58516917; called by muse, mutect2, varscan2
- MIA2 | c.857C>G p.T286R | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV54499311, COSV99698415; called by muse, mutect2, varscan2
- MOCS1 | c.1855_1857del p.E619del | In Frame Del (DEL) | VAF 62/144 reads (43%) | catalogued as rs760828381; called by pindel, varscan2
- PLXNB2 | c.3172C>T p.P1058S | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV63784323; called by muse, mutect2, varscan2
- RASEF | c.2069G>A p.S690N | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377721011; called by muse, mutect2, varscan2
- SLC34A1 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs147711480, COSV53691558; called by muse, mutect2, varscan2
- SLC37A1 | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs955999973; called by muse, mutect2, varscan2
- TDRD6 | c.1682A>G p.D561G | Missense Mutation (SNP) | VAF 151/335 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1444506034; called by muse, mutect2, varscan2
- TECTA | c.4610C>T p.P1537L | Missense Mutation (SNP) | VAF 60/69 reads (87%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99878696; called by muse, mutect2, varscan2
- ZNF688 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs752898969; called by muse, mutect2, varscan2
- ADGRE1 | c.965G>T p.C322F | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARID4A | c.3601_3602del p.M1201Vfs*5 | Frame Shift Del (DEL) | VAF 46/112 reads (41%) | called by pindel, varscan2
- ATRX | c.1399A>T p.K467* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- BIN2 | c.1021A>T p.N341Y | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BMT2 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CEP70 | c.1339A>G p.M447V | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNTNAP5 | c.2510T>A p.F837Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- EGFR | c.1130G>A p.R377K | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAREM1 | c.399_425del p.S134_E142del | In Frame Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, varscan2
- GLMN | c.1760C>G p.S587C | Missense Mutation (SNP) | VAF 58/60 reads (97%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- GPRIN1 | c.2113C>A p.P705T | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- HADHB | c.658A>T p.S220C | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- KIAA1191 | c.849_852del p.K283Nfs*14 | Frame Shift Del (DEL) | VAF 27/52 reads (52%) | called by pindel, varscan2
- LTBP3 | c.2033A>T p.N678I | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MED12L | c.72del p.Y25Tfs*15 | Frame Shift Del (DEL) | VAF 42/61 reads (69%) | called by mutect2, pindel, varscan2
- MEF2C | c.227A>T p.H76L | Missense Mutation (SNP) | VAF 22/309 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- MYCBP2 | c.5618_5621del p.S1873Lfs*2 (on ENST00000357337; = p.S1911Lfs*2 on NM_015057.5) | Frame Shift Del (DEL) | VAF 51/98 reads (52%) | called by mutect2, pindel, varscan2
- SNRPN | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SSB | c.1097_1099del p.S366_D367delinsN | In Frame Del (DEL) | VAF 42/101 reads (42%) | called by mutect2, pindel, varscan2
- SUOX | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- TENM2 | c.4459G>T p.V1487F (on ENST00000518659 / NM_001122679.2; = p.V1248F on NM_001080428.3) | Missense Mutation (SNP) | VAF 138/272 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TUT7 | c.3195_3198del p.I1065Mfs*18 | Frame Shift Del (DEL) | VAF 68/228 reads (30%) | called by mutect2, pindel, varscan2
- VPS13B | c.8138T>C p.I2713T | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- VWA3B | c.3484C>A p.H1162N | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ZNF592 | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- AEBP1 | c.2109G>C p.P703= | Silent (SNP) | VAF 33/56 reads (59%) | catalogued as rs774283193; called by muse, mutect2, varscan2
- CCDC8 | c.1422G>A p.Q474= | Silent (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- CEP162 | c.954T>C p.D318= | Silent (SNP) | VAF 63/133 reads (47%) | called by muse, mutect2, varscan2
- EHD3 | c.1380C>A p.G460= | Silent (SNP) | VAF 105/248 reads (42%) | called by muse, mutect2, varscan2
- ELN | c.660C>G p.P220= | Silent (SNP) | VAF 104/231 reads (45%) | catalogued as COSV52712220; called by muse, varscan2
- ERN2 | c.1848C>G p.V616= | Silent (SNP) | VAF 68/151 reads (45%) | catalogued as COSV55623669; called by muse, mutect2, varscan2
- FLRT2 | c.1647C>A p.G549= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as rs35699071, COSV100419855; called by muse, mutect2, varscan2
- GHDC | c.1230G>A p.V410= | Silent (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- INTS9 | c.771C>T p.N257= | Silent (SNP) | VAF 56/154 reads (36%) | called by muse, mutect2, varscan2
- IPO5 | c.1608A>G p.P536= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as rs1470144875; called by muse, mutect2, varscan2
- MCPH1 | c.576C>T p.P192= | Silent (SNP) | VAF 22/33 reads (67%) | called by muse, mutect2, varscan2
- NUDT22 | c.273G>A p.L91= | Silent (SNP) | VAF 42/73 reads (58%) | called by muse, mutect2, varscan2
- OR10H2 | c.174C>T p.P58= | Silent (SNP) | VAF 231/709 reads (33%) | called by muse, mutect2, varscan2
- OR3A1 | c.834A>T p.G278= | Silent (SNP) | VAF 56/144 reads (39%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1911G>A p.A637= | Silent (SNP) | VAF 122/274 reads (45%) | catalogued as rs553803944; called by muse, mutect2, varscan2
- SLC6A18 | c.1392G>A p.G464= | Silent (SNP) | VAF 41/91 reads (45%) | called by mutect2, varscan2
- TFEB | c.1393C>A p.R465= | Silent (SNP) | VAF 74/151 reads (49%) | called by muse, mutect2, varscan2
- WDR27 | c.2112C>T p.L704= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs772692794; called by muse, mutect2, varscan2
- ZNF582 | c.172C>T p.L58= | Silent (SNP) | VAF 51/118 reads (43%) | called by muse, mutect2, varscan2
